Surgical pathology report (de-identified scan), TCGA case TCGA-FG-7641, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-7641-01B (Primary Tumor).

[REDACTED]

SURGICAL PATHOLOGY REPORT

Addendum Present

Date of Procedure: [REDACTED]
Date Received: [REDACTED]

Race: [REDACTED]
DOB/Sex: [REDACTED]

FINAL DIAGNOSIS

A. LEFT FRONTAL BRAIN MASS, REMOVAL:
-- OLIGODENDROGLIOMA (WHO GRADE II).

Note: Occasional mitotic figures are identified. There is no microvascular proliferation or necrosis. An addendum will be issued pending analysis of chromosomes 1p and 19q.

Electronically Signed Out By By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A. Microscopic and touch imprints: Giloma.

Addendum/Procedures:

Addendum

Date Ordered: [REDACTED]
Date Complete: [REDACTED]

Status: Signed Out

Addendum Diagnosis

Fluorescence in situ hybridization, performed at the [REDACTED], demonstrates **loss of both chromosomes 1p and 19q**.

Electronically Signed Out By

Clinical History:

L frontal brain mass

Specimens Submitted As:

A: LEFT FRONTAL MASS

Gross Description:

A: Received fresh for intraoperative consultation, labeled with patient's name, hospital number, is an irregular fragment of pink-tan soft tissue fragment, 3.5 x 2.5 x 1 cm. A touch imprint is performed. A portion is sent for frozen section. The remainder of the specimen is submitted entirely for permanent in 3 cassettes.

Summary cassettes

A	1fs	portion of the specimen
	2-3	remainder of the specimen

Source: NCI Genomic Data Commons file 966172d0-3f98-49b1-be68-fb7e315e1e64 (TCGA-FG-7641.0F5772CF-B2C8-4872-A05D-58457E1E7875.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).